Somatic mutation profile of tumor specimen TCGA-ET-A25I-01A (aliquot TCGA-ET-A25I-01A-11D-A16O-08) from TCGA case TCGA-ET-A25I, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 37.7 years (13,786 days).
Specimen TCGA-ET-A25I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7df366b6-234a-401a-8bac-51e1d0de654b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A25I-10A (Blood Derived Normal), aliquot TCGA-ET-A25I-10A-01D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f050b36b-64c4-4840-8e87-539a48bff21e

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 60/209 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- GAB4 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 20/279 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763580378, COSV68753050, COSV68754617; called by muse, mutect2
- ITPRID1 | c.2040G>T p.R680S | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as COSV60079353; called by muse, mutect2, varscan2
- LAMC1 | c.482C>G p.A161G | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV51157722; called by muse, mutect2, varscan2
- NHS | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.288); catalogued as rs1326084438, COSV66279260; called by muse, mutect2, varscan2
- SYNE3 | c.1953C>G p.C651W | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV62081162; called by muse, mutect2, varscan2
- UNC45B | c.2304C>A p.N768K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.164); catalogued as COSV52098717; called by muse, varscan2
- ZFHX4 | c.9166C>T p.R3056W | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1466122982, COSV50666483; called by muse, mutect2
- TG | c.2462_2466del p.I821Kfs*4 | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | called by mutect2, pindel, varscan2
- PCDHA6 | c.1863G>A p.P621= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as rs782199993, COSV65343457; called by muse, mutect2, varscan2
- PLXNB3 | c.1101G>A p.S367= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as rs558515318, COSV62799683; called by muse, mutect2, varscan2
- TTF1 | c.1561T>C p.L521= | Silent (SNP) | VAF 57/169 reads (34%) | catalogued as COSV57506204; called by muse, mutect2, varscan2
- VWA7 | c.2571C>T p.F857= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
